Surgical pathology report (de-identified scan), TCGA case TCGA-YC-A8S6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Spectrum Health, specimen TCGA-YC-A8S6-01A (Primary Tumor).

[page 1 of 3]
Research Gross Description

-year-old male with bladder cancer

Research Dx

A. Right pelvic lymph nodes, right pelvic lymph node dissection:
One benign lymph node (0/1).

B. Left distal ureter:
Negative for tumor.

C. Right obturator lymph nodes:
Three benign lymph nodes (0/3).

D. Left pelvic lymph nodes, left pelvic lymph node dissection:
Eight benign lymph nodes (0/8).

E. Bladder and prostate:

✓ Papillary urothelial carcinoma, muscle invasive, high grade (see case summary).
Prostatic adenocarcinoma (see case summary).

F. Left common iliac lymph nodes:
Four benign lymph nodes (0/4).

G. Left ureteral margin:
Negative for tumor.

H. Urethral margin:
Negative for tumor.

I. Left distal ureter #3:
Negative for tumor.

CASE SUMMARY FOR URINARY BLADDER (CYSTECTOMY, PARTIAL, TOTAL OR RADICAL; ANTERIOR EXENTERATION):

Specimen: Bladder

Procedure: Radical cystoprostatectomy

Tumor site: First focus of tumor involves right wall, left wall, posterior wall and trigone and second focus of tumor involves anterior wall

Tumor size: First focus of tumor measures 5.7 cm and the second focus of tumor measures 2 cm

Histologic type: Urothelial (transitional) carcinoma

Associated epithelial lesions: Not identified

Histologic grade (WHO 2004/ISUP): High grade

Tumor configuration: Papillary

Microscopic tumor extension: Tumor invades superficial muscularis propria (inner half)

Margins: Negative

Lymphovascular Invasion: A focal area suspicious for lymphovascular invasion

Pathologic staging (pTNM):

Primary tumor: pT2a (tumor invades superficial muscularis propria (inner half)

Regional lymph nodes: Negative

Number examined: 16

Number involved: 0

Distant metastasis: Not applicable (per clinical)

Additional pathologic findings: Not identified

ICD-O-3
Carcinoma, papillary urothelial
8130/3
Site: Bladder
C67.9
JY 11/17/14

[page 2 of 3]
AJCC Staging (7th edition): pT2a, pN0, pM: Not applicable (per clinical)

CASE SUMMARY FOR PROSTATE GLAND (RADICAL PROSTATECTOMY):

Prostate size:

Weight: Unknown

Dimensions: 4.5 x 3.6 x 2.5 cm

Lymph node sampling: Bilateral pelvic lymph node dissection

Histologic type: Acinar adenocarcinoma

Histologic grade:

Gleason grade: 3+3 = 6

Tumor quantitation:

Proportion (percent) involved by tumor: less than 20%(multifocal on right side and unifocal left side)

Tumor size (dominant nodule, if present): Not applicable

Extraprostatic extension: Focal extra prostatic extension on the left side involving an area measuring 2 mm in length

Seminal vesicle invasion: Not identified

Margins: Negative

Treatment effect on carcinoma: Not identified

Lymphovascular invasion: Not identified

Perineural invasion: Present

Pathologic staging (pTNM):

Primary tumor: pT3 (extraprostatic extension)

Regional lymph nodes: pN0 (no regional lymph node metastasis)

Number involved: 0

Number examined: 16

Distant metastasis: pM: Not applicable (per clinical)

Additional pathologic findings: Not identified

AJCC Staging (7th edition) pT3, pN0, pM: Not applicable (per clinical)

Research QC

Tumor T1:

50% tumor nuclei (high grade urothelial carcinoma)

0% necrosis

50% normal (subepithelial connective tissue and muscularis propria)

Tumor T2:

50% tumor nuclei (high grade urothelial carcinoma)

0% necrosis

50% normal (subepithelial connective tissue and muscularis propria)

Normal N1:

100% bladder wall

Research Specimen

—

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

[page 3 of 3]
Buffy coat frozen time:

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Frozen start time:

Total cold ischemia time: 18 minutes

Formalin fixation stop time:

Total formalin fixation time: Greater than 6 and less than 72 hours

Specimen Weight

Normal

1-214 mg, 2-352 mg

Tumor

1-230 mg, 2-225 mg_

Specimen Size

Plasma x 3

Serum x 1

Buffy coat x 1

Cryovials x 4-bladder

Normal x 2

Tumor x 2

Metastatic x 0

FFPE x 4

Normal x 2

Tumor x 2

Metastatic x 0

Study

Patient Consent

Yes

Criteria: hw 11/24/13	Yes	No

Source: NCI Genomic Data Commons file d24664c2-82b7-4eed-9e7d-57618cef594c (TCGA-YC-A8S6.9945C51F-169C-48D5-81FC-9BFEA1C276C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).